Gene-level copy-number profile of specimen HCM-BROD-0029-C71-85C from HCMI case HCM-BROD-0029-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 58.0 years (21,192 days).
Specimen HCM-BROD-0029-C71-85C: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7545b5c-944d-43cf-a158-e3517b64a8d5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0029-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/86efbd2e-48b3-4d14-80c3-ebefcadb4665

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 5,200; copy number 2: 47,585; copy number 3: 6,122; copy number 5: 6.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:6,866,658–6,880,626, 2 genes: OR7E136P, OR7E59P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,269,491–38,300,322, 6 genes, copy number 5 (within-gene range 3–5): TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.

Autosomal genes at a single copy (total copy number 1): 2,344. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
